Somatic mutation profile of tumor specimen TCGA-HB-A2OT-01A (aliquot TCGA-HB-A2OT-01A-11D-A21Q-09) from TCGA case TCGA-HB-A2OT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.4 years (28,632 days).
Specimen TCGA-HB-A2OT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f200d11-a3d0-430f-aa72-94bc5f9f24e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HB-A2OT-10A (Blood Derived Normal), aliquot TCGA-HB-A2OT-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef56c9f2-2f0a-43d7-8b4d-410483f86603

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Nonsense Mutation 5, Frame Shift Del 4, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV100008773; called by muse, varscan2
- ACO1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100008779, COSV59380812; called by muse, varscan2
- ADAMTS8 | c.2530T>C p.C844R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961707; called by muse, mutect2, varscan2
- ADRA2B | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as COSV101337396; called by muse, mutect2, varscan2
- ANKK1 | c.1853A>T p.N618I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as COSV100393142; called by muse, mutect2, varscan2
- ATRX | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV64878305; called by muse, mutect2, varscan2
- B4GALNT1 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1417779034, COSV100356562; called by muse, mutect2
- CDKN1A | c.124A>C p.I42L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99781757; called by muse, mutect2, varscan2
- CECR2 | c.1801C>T p.R601C (on ENST00000342247 / NM_001290047.2; = p.R418C on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs767796133, COSV99379346; called by muse, mutect2, varscan2
- CFAP54 | c.4899G>T p.W1633C | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733419; called by muse, mutect2, varscan2
- COX16 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as COSV101112192, COSV66303380; called by muse, mutect2, varscan2
- CYP4F11 | c.649A>G p.K217E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.672); catalogued as rs1176436259, COSV99931155; called by muse, mutect2, varscan2
- DCLK3 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV101374173; called by muse, mutect2, varscan2
- DLX4 | c.434C>A p.P145H (on ENST00000240306 / NM_138281.3; = p.P73H on NM_001934.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537811; called by muse, mutect2, varscan2
- DNAH10 | c.6382C>T p.R2128C (on ENST00000409039; = p.R2067C on NM_207437.3) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777960375, COSV101292945, COSV68998172; called by muse, mutect2, varscan2
- DYNC2H1 | c.11735A>T p.D3912V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV100519988; called by muse, mutect2, varscan2
- EEA1 | c.2430A>C p.K810N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100468670; called by muse, mutect2, varscan2
- FANCB | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146538, COSV100146715; called by muse, mutect2, varscan2
- FOCAD | c.1373A>C p.H458P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100620753; called by muse, mutect2, varscan2
- FREM2 | c.8435C>A p.T2812N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99751449; called by muse, mutect2, varscan2
- GABRA5 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1433011366, COSV100165899; called by muse, mutect2, varscan2
- GBP4 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs75750014, COSV63254858; called by muse, mutect2, varscan2
- GRIK3 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV66143652, COSV66147075; called by mutect2, varscan2
- GSX1 | c.601A>G p.K201E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100262645; called by muse, mutect2, varscan2
- HK2 | c.2365C>G p.Q789E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.399); catalogued as rs780880800, COSV99308380, COSV99309693; called by muse, mutect2, varscan2
- HUWE1 | c.10759-1G>T p.X3587_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99474752; called by muse, mutect2
- JPH3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780773717, COSV52465346; called by muse, mutect2, varscan2
- KCNK9 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs774431836, COSV100271848, COSV57289066; called by muse, mutect2, varscan2
- LILRB5 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs758542287, COSV100300909; called by muse, mutect2, varscan2
- LPL | c.1348G>C p.V450L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs755628740, COSV100255873; called by muse, mutect2, varscan2
- MRC1 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100509742; called by muse, mutect2, varscan2
- MUC16 | c.17223C>A p.H5741Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101202077; called by muse, mutect2
- MYOCD | c.2664A>T p.E888D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV100591544; called by muse, mutect2, varscan2
- MYT1L | c.165T>A p.C55* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV101221559; called by muse, mutect2, varscan2
- OR2G2 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100190054; called by muse, mutect2, varscan2
- PADI3 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100968615; called by muse, mutect2, varscan2
- PCLO | c.10501A>C p.M3501L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100439094; called by muse, mutect2, varscan2
- PIK3CA | c.2656A>G p.K886E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.497); catalogued as COSV99844887; called by muse, mutect2, varscan2
- PPARGC1B | c.2561C>G p.S854* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100495280; called by muse, mutect2, varscan2
- PRKG1 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV100914956; called by muse, mutect2, varscan2
- PRSS16 | c.700A>T p.I234F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV100042044; called by muse, mutect2, varscan2
- RHPN2 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs199630139; called by muse, mutect2, varscan2
- SEZ6L2 | c.814C>T p.R272W (on ENST00000308713 / NM_001114099.3; = p.R202W on NM_012410.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs776157439, COSV58101157; called by muse, mutect2, varscan2
- SIRT3 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs199874973, COSV100291615; called by muse, mutect2, varscan2
- TOP2A | c.3726A>T p.E1242D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV101352327; called by muse, mutect2, varscan2
- TSSK1B | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs371461523; called by mutect2, varscan2
- UNC93B1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1429067086, COSV99916578; called by muse, mutect2, varscan2
- ZNF419 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99692722; called by muse, mutect2, varscan2
- EBF1 | c.1769_1770del p.P590Hfs*7 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- IRAG1 | c.376del p.S126Pfs*5 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- KIAA1109 | c.7424del p.L2475Wfs*28 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- PROSER1 | c.1827_1828del p.E610Afs*47 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | called by mutect2, pindel, varscan2
- SETBP1 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- TRBV4-1 | c.197T>G p.F66C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCAN | c.1795C>A p.R599= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100228561, COSV61256351; called by muse, mutect2
- CFAP206 | c.123C>G p.V41= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99740213; called by muse, mutect2, varscan2
- CPAMD8 | c.1749T>A p.A583= (on ENST00000651564; = p.A536= on NM_015692.5) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99359900; called by muse, mutect2, varscan2
- GRK3 | c.1512A>G p.E504= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs777476965, COSV100152090; called by muse, mutect2, varscan2
- INS-IGF2 | c.7C>T p.L3= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99171172, COSV99171175; called by muse, mutect2, varscan2
- KMT2D | c.2088C>T p.S696= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1266461322, COSV99986459; called by muse, mutect2
- LRRC30 | c.93C>T p.D31= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV101274471; called by muse, mutect2, varscan2
- MACF1 | c.8853A>G p.V2951= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs773909632, COSV99247385; called by muse, varscan2
- MPPED1 | c.301A>C p.R101= | Silent (SNP) | VAF 52/83 reads (63%) | catalogued as COSV100501360; called by muse, mutect2, varscan2
- OR51S1 | c.474T>C p.F158= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs771873712, COSV100437600; called by muse, mutect2, varscan2
- PRSS1 | c.312G>T p.L104= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV100298548; called by muse, mutect2, varscan2
- PRSS55 | c.240G>A p.P80= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs769990390, COSV100153904; called by muse, mutect2, varscan2
- PTPRT | c.3288C>T p.A1096= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100631162; called by muse, mutect2, varscan2
- WDCP | c.39G>C p.L13= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99722269; called by muse, mutect2, varscan2
- ZDHHC4 | c.330A>G p.V110= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100254114; called by muse, mutect2, varscan2
- ZNF608 | c.834C>T p.N278= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100102582; called by muse, mutect2
- VN1R10P | n.496T>C | RNA (SNP) | VAF 10/32 reads (31%) | catalogued as rs775473742; called by muse, mutect2, varscan2
